TCGA case TCGA-N8-A4PM — Uterine Carcinosarcoma (TCGA-UCS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Complex Mixed and Stromal Neoplasms; Primary site: Corpus uteri; Tissue source site: University of North Carolina. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/eec002c4-7602-4179-8eb3-2b0508d5ee1c

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 73 years; Vital status: Alive.

Diagnoses (3)
1. Carcinosarcoma, NOS (the primary disease): ICD-O-3 morphology code: 8980/3; ICD-10 code: C54.3; Tissue or organ of origin: Fundus uteri; Site of resection or biopsy: Uterus, NOS; Classification of tumor: primary; Age at diagnosis: 73.8 years (26,971 days); Year of diagnosis: 2011; Method of diagnosis: Biopsy; FIGO stage: Stage IB; FIGO staging edition year: 2009; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 829 days (2.3 years).
   Pathology details: Lymph node involved site: Pelvis, NOS; Lymph nodes positive: 0; Lymph nodes tested: 14.
   Pathology details: Consistent pathology review: Yes; Percent tumor invasion: 63.
   Pathology details: Lymph node involved site: Aortic; Lymph nodes positive: 0; Lymph nodes tested: 11.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Paclitaxel; Days to treatment start: 98 days; Days to treatment end: 161 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Surgery, Minimally Invasive; Initial disease status: Initial Diagnosis.
   Recorded, whether given is unknown: Pharmaceutical Therapy, NOS (Tamoxifen), prior to diagnosis.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Phyllodes tumor, malignant: ICD-O-3 morphology code: 9020/3; Tissue or organ of origin: Breast, NOS; Laterality: Left; Classification of tumor: Prior primary; Age at diagnosis: 70.7 years (25,837 days); Days to diagnosis: -1,134 days (-3.1 years).
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: -1,134 days (-3.1 years); Treatment anatomic sites: Breast.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
3. Recurrence of diagnosis 1 (Carcinosarcoma, NOS), site: Lymph node, NOS. Age at diagnosis: 75.3 years (27,495 days); Days to diagnosis: 524 days (1.4 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease; Surgery, NOS, for recurrent disease.

Follow-up (3 entries)
- Days to follow up: 497 days (1.4 years); Disease response: Tumor Free.
- Day 524 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Lymph node, NOS; Days to recurrence: 524 days (1.4 years).
- Days to follow up: 829 days (2.3 years); Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 92 kg; Height: 155 cm; BMI: 38.3.
- Timepoint category: Prior to Diagnosis; Hormonal replacement therapy status: No; Menopause status: Postmenopausal; Number of pregnancies: 1; Pregnancy outcome: Full Term Birth, NOS; Risk factors: Hypertension.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-N8-A4PM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 660 mg.
  Slide TCGA-N8-A4PM-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-N8-A4PM-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-N8-A4PM-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); History menopausal hormone therapy: No, I have never taken menopausal hormone therapy; Hypertension diagnosis: Yes; Diabetes diagnosis indicator: No; Pregnancies full term count: 1; History colorectal cancer: No; History neoadjuvant treatment: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response.
- Primary pathology: Submitted tumor site: Uterus; Histologic diagnosis: Uterine Carcinosarcoma/MMMT: Homologous Type; Surgical approach at diagnosis: Minimally Invasive; Method initial path diagnosis: Office Endometrial Biopsy.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor; Treatment outcome first course: Complete Remission/Response.
- Drug treatment 1: Pharmaceutical therapy drug name: Taxol.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Breast; Other malignancy histological type: Phyllodes tumor.
- Other malignancy form, Surgery: Other malignancy surgery type: Mastectomy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 829 days; disease-specific survival: no event (censored), 829 days; disease-free interval: event (new tumor event after initially disease-free), 524 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 524 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-N8-A4PM-01A-11D-A28Q-01): tumor purity 0.9, ploidy 3.75, whole-genome doublings 1.
